Somatic mutation profile of tumor specimen TCGA-12-3650-01A (aliquot TCGA-12-3650-01A-01W-0922-08) from TCGA case TCGA-12-3650, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 46.9 years (17,138 days).
Specimen TCGA-12-3650-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8f2037d-e514-44ca-b4a0-9b13f563e32a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-3650-10A (Blood Derived Normal), aliquot TCGA-12-3650-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/009b4458-4158-41ef-816f-ed7e4eecba48

The open-access MAF lists 54 somatic variants for this specimen: 38 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 15, Nonsense Mutation 4, RNA 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS13 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV63023098; called by muse, mutect2, varscan2
- ADH1B | c.943T>G p.W315G | Missense Mutation (SNP) | VAF 149/384 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59298650; called by muse, mutect2, varscan2
- C18orf21 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs779395246, COSV52449661; called by muse, mutect2, varscan2
- C6orf118 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 92/222 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs768960595, COSV100023958, COSV57819001; called by muse, mutect2, varscan2
- CACNG3 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 108/273 reads (40%) | catalogued as COSV50082807; called by muse, mutect2, varscan2
- CCNE1 | c.1089C>G p.H363Q | Missense Mutation (SNP) | VAF 121/409 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52905740; called by muse, mutect2, varscan2
- CD300C | c.402C>T p.A134= | Splice Region (SNP) | VAF 66/176 reads (38%) | catalogued as rs764035212, COSV58171417; called by muse, mutect2, varscan2
- CFHR2 | c.520G>T p.V174F | Missense Mutation (SNP) | VAF 139/273 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV66382206; called by muse, mutect2, varscan2
- CNPY4 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV53542766; called by muse, mutect2, varscan2
- COL11A1 | c.1258G>T p.G420C | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV62196883; called by muse, mutect2, varscan2
- DRGX | c.98A>C p.Q33P | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV65137562; called by muse, mutect2, varscan2
- EPB41L2 | c.452G>C p.S151T | Missense Mutation (SNP) | VAF 451/1221 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV100441288, COSV61358968; called by muse, mutect2, varscan2
- FLNA | c.3572C>T p.A1191V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV61047655; called by muse, mutect2
- FLNC | c.5686G>A p.V1896M | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs891651799, COSV57964651; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXJ3 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1300696727, COSV62362513; called by muse, mutect2, varscan2
- HNF4A | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 46/123 reads (37%) | catalogued as CM133291, COSV57389048; called by muse, mutect2
- HSPA6 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs1157013376, COSV59059948; called by muse, mutect2, varscan2
- KIAA1210 | c.3518G>A p.R1173Q | Missense Mutation (SNP) | VAF 36/47 reads (77%) | SIFT tolerated (0.22); PolyPhen benign (0.217); catalogued as rs188369194, COSV101274441, COSV68177061; called by muse, mutect2, varscan2
- LILRB5 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.772); catalogued as rs763749586, COSV100300359; called by muse, mutect2
- MAPK7 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55189761; called by muse, mutect2, varscan2
- MROH8 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as COSV54124592; called by muse, mutect2, varscan2
- MUC16 | c.24520G>A p.V8174M | Missense Mutation (SNP) | VAF 174/629 reads (28%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.02); catalogued as rs1167493424, COSV67492334; called by muse, mutect2, varscan2
- PC | c.793T>G p.C265G | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63082603; called by muse, mutect2, varscan2
- PDZRN4 | c.2879G>A p.R960H (on ENST00000402685 / NM_001164595.2; = p.R702H on NM_013377.4) | Missense Mutation (SNP) | VAF 108/228 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748727154, COSV54216779; called by muse, mutect2, varscan2
- PKP2 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs149542398, CM1511405; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- PLB1 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as COSV59835285; called by muse, mutect2, varscan2
- RAB39B | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 114/133 reads (86%) | catalogued as COSV65625190, COSV65625199; called by muse, mutect2, varscan2
- SLIT3 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138901310; called by muse, mutect2, varscan2
- SPAM1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs762640029, COSV56147612; called by muse, mutect2, varscan2
- TACR3 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 91/213 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100510729, COSV59208503; called by muse, mutect2, varscan2
- TFAP2D | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 129/343 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776969911, COSV50411184, COSV50453941; called by muse, mutect2, varscan2
- VEGFC | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs566826535, COSV54604159; called by muse, mutect2, varscan2
- VEGFD | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 52/60 reads (87%) | catalogued as rs752152727, COSV52911010; called by muse, mutect2, varscan2
- YME1L1 | c.1099C>T p.L367F (on ENST00000326799 / NM_139312.3; = p.L310F on NM_014263.4) | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58761477; called by muse, mutect2, varscan2
- ZBTB10 | c.2597G>T p.C866F (on ENST00000430430; = p.C842F on NM_023929.4) | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV66948545; called by muse, mutect2, varscan2
- ZNF569 | c.673C>G p.H225D | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV57599031; called by muse, mutect2, varscan2
- ARHGAP33 | c.2744dup p.A916Cfs*12 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by pindel, varscan2
- SLC44A5 | c.1534C>A p.H512N | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ABCC11 | c.3504C>T p.H1168= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs143002804; called by muse, mutect2, varscan2
- CHRNB4 | c.783C>T p.G261= | Silent (SNP) | VAF 193/400 reads (48%) | catalogued as rs755812541, COSV55715505, COSV55718283; called by muse, mutect2, varscan2
- EML2 | c.1794C>T p.H598= | Silent (SNP) | VAF 83/298 reads (28%) | catalogued as COSV55603885; called by muse, mutect2, varscan2
- GAS2L2 | c.2031G>A p.P677= | Silent (SNP) | VAF 40/70 reads (57%) | catalogued as rs782602530; called by muse, mutect2, varscan2
- HOXB1 | c.522C>A p.T174= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV53318646; called by muse, mutect2, varscan2
- IQSEC3 | c.1461C>T p.D487= (on ENST00000538872 / NM_001170738.2; = p.D184= on NM_015232.1) | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV58284098; called by muse, mutect2, varscan2
- IRF4 | c.927C>T p.S309= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- MS4A1 | c.291C>T p.S97= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as rs201962059, COSV61943023; called by muse, mutect2, varscan2
- OR13C9 | c.951C>T p.S317= | Silent (SNP) | VAF 216/575 reads (38%) | catalogued as COSV52243624; called by muse, mutect2, varscan2
- SGTB | c.342G>A p.L114= | Silent (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- SLC13A4 | c.1272C>T p.L424= | Silent (SNP) | VAF 49/202 reads (24%) | catalogued as COSV62462764; called by muse, mutect2, varscan2
- SLC6A19 | c.1110C>T p.S370= | Silent (SNP) | VAF 61/160 reads (38%) | catalogued as rs564673494, COSV58674486; called by muse, mutect2, varscan2
- STK32B | c.787C>T p.L263= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as COSV51512386; called by muse, mutect2, varscan2
- TAF1L | c.4899T>A p.L1633= | Silent (SNP) | VAF 141/317 reads (44%) | catalogued as COSV54268949; called by muse, mutect2, varscan2
- TMEM38A | c.234C>T p.I78= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as rs144587502; called by muse, mutect2, varscan2
- HERC2P3 | n.1168C>T | RNA (SNP) | VAF 34/87 reads (39%) | catalogued as rs539212963; called by muse, mutect2, varscan2
